Somatic mutation profile of tumor specimen TCGA-KS-A4I1-01A (aliquot TCGA-KS-A4I1-01A-11D-A257-08) from TCGA case TCGA-KS-A4I1, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.1 years (13,538 days).
Specimen TCGA-KS-A4I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e35c00f-efb8-4e11-abd1-18366a0631d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KS-A4I1-11A (Solid Tissue Normal), aliquot TCGA-KS-A4I1-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eed60b18-513e-4511-bb2d-32770657758e

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- JAKMIP1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs745353291, COSV51547338; called by muse, mutect2, varscan2
- PCDH11X | c.1234T>C p.F412L | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.925); catalogued as COSV100007328; called by muse, mutect2
- PLEC | c.4888C>A p.Q1630K (on ENST00000322810 / NM_201380.4; = p.Q1520K on NM_000445.5) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.332); catalogued as COSV100509450; called by muse, mutect2
- TMLHE | c.121T>G p.W41G | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100544545; called by muse, mutect2, varscan2
- MSLN | c.435G>A p.T145= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs371797682; called by muse, mutect2, varscan2
- SLIT2 | c.645C>T p.C215= | Silent (SNP) | VAF 98/269 reads (36%) | catalogued as rs1252936803, COSV99880150; called by muse, mutect2, varscan2
- TLE3 | c.330C>T p.R110= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs376875838; called by muse, varscan2
